Somatic mutation profile of tumor specimen MMRF_2458_1_BM_CD138pos (aliquot MMRF_2458_1_BM_CD138pos_T1_KHS5U_L11089) from MMRF case MMRF_2458, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,565 days).
Specimen MMRF_2458_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52b4c92b-a29a-437f-acde-f61299a59adc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2458_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2458_1_PB_Whole_C3_KHS5U_L11090; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a150406-3593-46ef-8f0a-5cf5551da8a2

The open-access MAF lists 135 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 33, Silent 13, Intron 12, 5'UTR 7, 5'Flank 4, Splice Region 4, 3'Flank 4, RNA 4, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 53/146 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 20/147 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- BRINP3 | c.1184+1G>T p.X395_splice | Splice Site (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100819649; called by muse, mutect2, varscan2
- CDKN1B | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 103/174 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV104391593, COSV57431481; called by muse, mutect2, varscan2
- COBLL1 | c.1935A>C p.E645D (on ENST00000392717; = p.E607D on NM_014900.5) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV52076337; called by muse, mutect2, varscan2
- CPVL | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 113/234 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV55308476; called by muse, mutect2, varscan2
- DES | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV64660914; called by muse, mutect2, varscan2
- FAT4 | c.14094C>A p.N4698K | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100629005, COSV100629070; called by muse, mutect2, varscan2
- FNBP1L | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774614978, COSV53091412; called by muse, mutect2, varscan2
- IGKV2-24 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766739646; called by muse, mutect2, varscan2
- IGLV3-1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as rs61731687; called by muse, mutect2, varscan2
- LGI1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1263918669, COSV101004393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.2891G>A p.S964N | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV67463496; called by muse, mutect2, varscan2
- PCDH18 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.38); catalogued as COSV100786975; called by muse, mutect2, varscan2
- PRICKLE2 | c.1652G>A p.R551Q (on ENST00000295902; = p.R495Q on NM_198859.4) | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.783); catalogued as rs762969341, COSV99898231; called by muse, mutect2, varscan2
- RAPGEF5 | c.693A>T p.K231N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV100686573; called by muse, mutect2, varscan2
- RUSF1 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV59131993; called by muse, mutect2, varscan2
- SLC5A3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62967960; called by muse, mutect2, varscan2
- ZBP1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs376946202; called by muse, mutect2, varscan2
- ZNF491 | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs559298015; called by muse, mutect2, varscan2
- ZNF831 | c.4667C>T p.S1556L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772575008, COSV64044166; called by muse, mutect2, varscan2
- ACADM | c.162C>G p.V54= | Splice Region (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ADAM29 | c.1715A>T p.H572L | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ALPK2 | c.3376T>G p.F1126V | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ASXL1 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- CASKIN2 | c.3105C>A p.S1035R | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC142 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CCDC71L | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CERCAM | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.11485C>T p.L3829F | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAH9 | c.1302G>T p.L434F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DOP1A | c.4045A>T p.M1349L | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLX | c.592+3A>C | Splice Region (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- HTR3E | c.389+6dup | Splice Region (INS) | VAF 23/59 reads (39%) | called by mutect2, pindel, varscan2
- KRT10 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- KRT10 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 115/217 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- KRTAP10-1 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MAP4K4 | c.508+6T>C | Splice Region (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- MEX3C | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MGA | c.413A>C p.N138T | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MTCL1 | c.1723G>T p.E575* (on ENST00000306329 / NM_001378206.1; = p.E215* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- MYPOP | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- OR51E1 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHA8 | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 76/206 reads (37%) | called by muse, mutect2, varscan2
- PIP4K2B | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRB3 | c.874C>A p.P292T (on ENST00000381842; = p.P334T on NM_006249.5) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PRSS38 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- SCN1A | c.2480A>T p.Y827F (on ENST00000303395 / NM_001202435.3; = p.Y816F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SIAE | c.477dup p.I160Hfs*14 | Frame Shift Ins (INS) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- SLC44A3 | c.1327T>G p.F443V (on ENST00000271227 / NM_001114106.3; = p.F395V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SMU1 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SPOCK1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- TEX47 | c.617A>C p.D206A | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- USH2A | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS26B | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 123/260 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF319 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF324B | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF521 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASP8AP2 | c.3594A>G p.K1198= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- CDH20 | c.2013C>T p.G671= | Silent (SNP) | VAF 138/219 reads (63%) | called by muse, mutect2, varscan2
- CDON | c.1020C>T p.A340= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.6717G>A p.K2239= | Silent (SNP) | VAF 35/210 reads (17%) | catalogued as rs1412818591; called by muse, mutect2, varscan2
- HAO1 | c.612A>G p.G204= | Silent (SNP) | VAF 75/145 reads (52%) | called by muse, mutect2, varscan2
- IGHA1 | c.30G>A p.P10= | Silent (SNP) | VAF 174/384 reads (45%) | catalogued as rs750572037; called by muse, mutect2, varscan2
- LGALS3BP | c.1203G>A p.E401= | Silent (SNP) | VAF 44/160 reads (28%) | called by muse, mutect2, varscan2
- MAP1LC3C | c.294C>T p.S98= | Silent (SNP) | VAF 102/199 reads (51%) | catalogued as rs200481799, COSV61803985; called by muse, mutect2, varscan2
- MTCL1 | c.1722G>A p.V574= (on ENST00000306329 / NM_001378206.1; = p.V214= on NM_015210.4) | Silent (SNP) | VAF 26/124 reads (21%) | called by muse, mutect2, varscan2
- SON | c.4833T>C p.G1611= | Silent (SNP) | VAF 84/181 reads (46%) | called by muse, mutect2, varscan2
- VAX2 | c.372C>T p.C124= | Silent (SNP) | VAF 67/150 reads (45%) | called by muse, mutect2, varscan2
- ZNF536 | c.670C>T p.L224= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ZNF800 | c.834T>C p.S278= | Silent (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- AC114940.2 | chr5:106543771 A>C | 5'Flank (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- ACBD3 | c.*47A>G | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as rs1409765601; called by muse, mutect2, varscan2
- APH1A | c.-57C>T | 5'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- ARMH4 | c.*3559_*3574del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ATP1A2 | c.*1842G>T | 3'UTR (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- BEND4 | c.*5371G>A | 3'UTR (SNP) | VAF 28/88 reads (32%) | catalogued as rs1001411468; called by muse, mutect2, varscan2
- C2CD6 | c.1581+2465A>C | Intron (SNP) | VAF 56/155 reads (36%) | called by muse, mutect2, varscan2
- CACNG5 | chr17:66885343 C>T | 3'Flank (SNP) | VAF 73/149 reads (49%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86067542 T>G | 3'Flank (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- CCDC191 | c.*40G>C | 3'UTR (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- DCAF16 | c.*25T>A | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- DCC | c.*1710A>G | 3'UTR (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- DSE | c.*463_*470del | 3'UTR (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- EPHA5 | c.*2717G>T | 3'UTR (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+242C>A | Intron (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- FAM102A | c.*922G>A | 3'UTR (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- FAM102B | c.*969T>G | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- FGA | c.-1G>T | 5'UTR (SNP) | VAF 68/228 reads (30%) | catalogued as rs539702396; called by muse, mutect2, varscan2
- FMN1 | c.2161+1015A>G | Intron (SNP) | VAF 38/151 reads (25%) | catalogued as rs981611554; called by muse, mutect2, varscan2
- FOXO1 | c.-132del | 5'UTR (DEL) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- GABRD | c.*34C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs372342447; called by muse, mutect2, varscan2
- HELLPAR | n.200870C>T | RNA (SNP) | VAF 21/51 reads (41%) | catalogued as rs1195496609; called by muse, mutect2, varscan2
- HNF4G | c.*229G>T | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- HSD17B3 | c.*33C>G | 3'UTR (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- LAMB1 | c.38-403A>T | Intron (SNP) | VAF 12/67 reads (18%) | catalogued as rs752247617; called by muse, mutect2, varscan2
- LINC01159 | n.23G>A | RNA (SNP) | VAF 7/45 reads (16%) | catalogued as rs1001957802; called by muse, mutect2, varscan2
- LRIF1 | c.*518G>T | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- MAD1L1 | c.1999-33309C>T | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- MAP3K1 | c.*1112A>T | 3'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- MAPK15 | c.779+81G>A | Intron (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- MFF | c.-112T>A | 5'UTR (SNP) | VAF 154/336 reads (46%) | called by muse, mutect2, varscan2
- MMP8 | c.*542T>G | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- NEMP2 | c.*1312A>T | 3'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- NKX3-1 | c.*1076T>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- NSD2 | c.*1786C>G | 3'UTR (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- NSUN3 | c.*170T>C | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, varscan2
- NSUN3 | c.*230T>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, varscan2
- OR4K2 | c.-18T>C | 5'UTR (SNP) | VAF 95/191 reads (50%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1055T>C | 3'UTR (SNP) | VAF 54/95 reads (57%) | catalogued as COSV100787514; called by muse, mutect2, varscan2
- PCMTD1 | c.*1823A>C | 3'UTR (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2
- PEF1 | chr1:31644990 T>G | 5'Flank (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- PEX2 | c.*2413A>T | 3'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- PKD1L2 | n.883dup | RNA (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel
- PLA2G10 | c.*54A>G | 3'UTR (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 6/74 reads (8%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- RAB32 | c.*45G>T | 3'UTR (SNP) | VAF 47/267 reads (18%) | called by muse, mutect2, varscan2
- RAB35 | chr12:120116861 G>A | 5'Flank (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- SDHAF3 | c.*370A>C | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- SERPINB5 | c.*92T>A | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- SLC2A11 | chr22:23856648 C>G | 5'Flank (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SLC8A3 | c.2408-351G>T | Intron (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- TASOR | c.4301-100C>G | Intron (SNP) | VAF 65/402 reads (16%) | called by muse, mutect2, varscan2
- TLCD4 | c.*5710del | 3'UTR (DEL) | VAF 56/125 reads (45%) | called by mutect2, pindel, varscan2
- TRAF1 | c.*2115C>G | 3'UTR (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- TRPM3 | c.979+17778T>G | Intron (SNP) | VAF 59/124 reads (48%) | catalogued as COSV100678471; called by muse, mutect2, varscan2
- TTC41P | n.2466G>A | RNA (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- UBE2H | c.*3470dup | 3'UTR (INS) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- UGT1A6 | c.862-11989G>A | Intron (SNP) | VAF 16/123 reads (13%) | catalogued as rs745537470; called by muse, mutect2, varscan2
- USP46 | c.*2885T>A | 3'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- VANGL1 | chr1:115693880 T>G | 3'Flank (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- VPS35L | c.1224+56G>A | Intron (SNP) | VAF 84/151 reads (56%) | catalogued as rs1483519456; called by muse, mutect2, varscan2
- VPS37B | c.111+6679C>G | Intron (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- WHAMMP3 | chr15:22690471 T>C | 3'Flank (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2
- WSCD2 | c.-252A>C | 5'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
